Gene-level copy-number profile of tumor specimen TCGA-BK-A139-01A from TCGA case TCGA-BK-A139, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.1 years (27,077 days).
Specimen TCGA-BK-A139-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.256ea8d6-4586-479a-899a-0988acf58f68.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BK-A139-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 416 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second ASCAT2 file; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/15be4899-b785-4c8b-a0bc-2c591afec4b2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 563; copy number 1: 924; copy number 2: 17,933; copy number 3: 17,823; copy number 4: 16,571; copy number 5: 3,251; copy number 6: 1,686; copy number 7: 470; copy number 8: 544; copy number 9: 171; copy number 10: 26; copy number 11: 15; copy number 12: 3; copy number 13: 182; copy number 14: 41; copy number 15: 1; copy number 26: 1; copy number 32: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BK-A139-01A-11D-A275-01): tumor purity 0.44, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:97,523,949–97,524,976, 1 gene: AC017099.1.
- chr3:23,804,024–23,980,617, 6 genes: UBE2E1-AS1, UBE2E1, ARL4AP4, NKIRAS1, RPL15, NR1D2.
- chr4:45,480,030–45,480,136, 1 gene: RNU6-931P.
- chr9:3,181,342–4,348,392, 10 genes (within-gene range 0–2): LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1, GLIS3, AL137071.1, GLIS3-AS1, AL359095.1.
- chr9:94,555,054–94,640,249, 3 genes (within-gene range 0–2): PCAT7, FBP2, FBP1.
- chr11:15,966,449–16,739,591, 1 gene (within-gene range 0–2): SOX6.
- chr11:16,484,084–16,758,340, 3 genes (within-gene range 0–2): AKR1B1P3, RN7SL188P, C11orf58.
- chr12:65,050,626–65,121,305, 2 genes (within-gene range 0–2): WIF1, RNU6-166P.
- chr14:24,007,185–24,027,782, 1 gene (within-gene range 0–2): AL136419.3.
- chr15:25,027,736–25,032,047, 1 gene: AC124312.2.
- chr15:25,104,642–25,108,352, 3 genes: SNORD116-28, SNORD116-29, SNORD116-30.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,142 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,298,149–62,298,256, 1 gene, copy number 15: RNU6-371P.
- chr2:97,113,153–97,589,965, 2 genes, copy number 9–14 (within-gene range 0–14): ANKRD36, ANKRD36B.
- chr2:97,618,638–97,664,044, 4 genes, copy number 9: AC017099.2, UBTFL6, COX5B, ACTR1B.
- chr2:97,664,591–97,664,731, 1 gene, copy number 9: RNU4-8P.
- chr4:53,899,871–56,966,808, 76 genes, copy number 8–11 (within-gene range 5–11) (broad region; genes not listed).
- chr4:58,103,147–59,630,324, 12 genes, copy number 7: SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1.
- chr4:146,638,893–146,642,474, 1 gene, copy number 13: POU4F2.
- chr5:58,198–45,895,970, 710 genes, copy number 7–12 (broad region; genes not listed).
- chr8:38,082,122–39,838,289, 45 genes, copy number 9–14 (within-gene range 2–14): AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2.
- chr8:53,388,701–54,871,720, 33 genes, copy number 7 (within-gene range 6–7): AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B, AC090151.1.
- chr8:90,621,995–90,791,632, 1 gene, copy number 7 (within-gene range 6–7): TMEM64.
- chr8:90,701,082–90,701,876, 1 gene, copy number 7: AC106038.2.
- chr8:90,806,474–90,859,240, 1 gene, copy number 7 (within-gene range 6–7): AC103770.1.
- chr8:141,117,278–145,066,685, 191 genes, copy number 7 (broad region; genes not listed).
- chr9:136,881,912–136,926,607, 1 gene, copy number 10 (within-gene range 2–10): TRAF2.
- chr9:136,935,840–137,109,183, 25 genes, copy number 10: AL807752.1, AL807752.5, FBXW5, C8G, LCN12, LINC02692, PTGDS, AL807752.7, LCNL1, PAXX, CLIC3, ABCA2, C9orf139, FUT7, AL807752.6, NPDC1, ENTPD2, AL807752.4, AL807752.2, SAPCD2, AL807752.3, UAP1L1, MAN1B1-DT, MAN1B1, SNORD62.
- chr10:93,893,973–93,956,062, 1 gene, copy number 9 (within-gene range 3–9): SLC35G1.
- chr10:95,109,136–95,111,642, 1 gene, copy number 26: AL157834.1.
- chr15:25,215,541–25,250,940, 20 genes, copy number 8: SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr18:54,269,404–54,898,083, 13 genes, copy number 8 (within-gene range 2–8): POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1.
- chr20:1,561,385–1,620,061, 2 genes, copy number 32 (within-gene range 4–32): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 757. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
